Somatic mutation profile of tumor specimen TCGA-AB-2934-03A (aliquot TCGA-AB-2934-03A-01W-0745-08) from TCGA case TCGA-AB-2934, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.6 years (23,956 days).
Specimen TCGA-AB-2934-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17829f69-1e6b-4b99-888d-0c0f8db863a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2934-11A (Solid Tissue Normal), aliquot TCGA-AB-2934-11A-01W-0745-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33cbe0be-5e2c-474a-a50b-9b5432cb70f0

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTLL12 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.16); catalogued as rs148865013; called by muse, mutect2
- ACHE | c.1284C>A p.A428= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
